Gene-level copy-number profile of tumor specimen TCGA-13-0761-01A from TCGA case TCGA-13-0761, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 51.2 years (18,697 days).
Specimen TCGA-13-0761-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.70bb7e2f-cb99-4960-a591-32e796c98f2f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0761-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/317b3d4a-d3bf-44d1-a753-2f6061868aaa

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 747; copy number 2: 11,773; copy number 3: 7,808; copy number 4: 28,752; copy number 5: 4,443; copy number 6: 4,993; copy number 7: 117; copy number 8: 18; copy number 9: 454; copy number 11: 192; copy number 12: 188; copy number 13: 330.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-13-0761-01): tumor purity 0.73, ploidy 3.87, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,164 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–16,697,479, 274 genes, copy number 9–12 (broad region; genes not listed).
- chr3:19,389,185–21,145,967, 15 genes, copy number 9 (within-gene range 4–9): AC061958.1, EFHB, HSPA8P18, RAB5A, PP2D1, RNU4-85P, SAP18P3, RPL39P18, KAT2B, MIR3135A, SGO1, SGO1-AS1, RNU6-822P, AC116096.1, RNU6-815P.
- chr3:196,598,549–198,222,513, 55 genes, copy number 9: AC092933.2, LINC01063, NRROS, PIGX, CEP19, RNU6-646P, PAK2, RNU4-89P, RNU6-42P, SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ, AC011322.1, RPSAP69, MELTF, MELTF-AS1, DLG1, MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr8:94,249,253–145,066,685, 820 genes, copy number 9–13 (within-gene range 6–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 747. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
